Somatic mutation profile of tumor specimen TCGA-06-5415-01A (aliquot TCGA-06-5415-01A-01D-1486-08) from TCGA case TCGA-06-5415, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.8 years (22,213 days).
Specimen TCGA-06-5415-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb038157-4c50-47ec-b88a-856a94a76f44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5415-10A (Blood Derived Normal), aliquot TCGA-06-5415-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14df70c2-824d-4767-8494-6675039f582c

The open-access MAF lists 51 somatic variants for this specimen: 35 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 28, Silent 16, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSG1 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 52/145 reads (36%) | catalogued as rs568609861, COSV57134949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.11156G>A p.R3719H | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs527236139, CM148283, COSV56321550; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CA11 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV50033074; called by muse, varscan2
- CAPS2 | c.924T>G p.D308E | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV60825730; called by muse, mutect2, varscan2
- DNAH2 | c.3841C>T p.R1281* | Nonsense Mutation (SNP) | VAF 109/271 reads (40%) | catalogued as rs778080261, COSV66719858; called by muse, mutect2, varscan2
- ERCC4 | c.847T>A p.S283T | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.297); catalogued as COSV61312133; called by muse, mutect2, varscan2
- FAM83H | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1292894616, COSV66353929; called by muse, mutect2, varscan2
- GABRA1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs775157869, COSV50098608; called by muse, mutect2, varscan2
- ITPRIPL2 | c.550C>G p.P184A | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV67347644; called by muse, mutect2, varscan2
- KEL | c.223+1G>A p.X75_splice | Splice Site (SNP) | VAF 34/123 reads (28%) | catalogued as rs369569464, CS012497, CS012498; called by muse, mutect2, varscan2
- KRTAP10-9 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs201090014; called by muse, mutect2, varscan2
- LCOR | c.1529G>A p.C510Y | Missense Mutation (SNP) | VAF 86/141 reads (61%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV53716060; called by muse, mutect2, varscan2
- MIB2 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.799); catalogued as rs750480310, COSV61542704; called by muse, mutect2, varscan2
- MMP10 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54246353; called by muse, mutect2, varscan2
- MTTP | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs371023325, COSV55505932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NMUR1 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs201125357, COSV59404309; called by muse, mutect2, varscan2
- NOS1 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1412760885, COSV57606502; called by muse, mutect2, varscan2
- NUP210L | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55148100; called by muse, mutect2, varscan2
- PCSK2 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52732903; called by muse, mutect2, varscan2
- PDE1C | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs377062465, COSV58518602; called by muse, mutect2, varscan2
- PLEKHG5 | c.142C>G p.L48V (on ENST00000400915 / NM_001042663.3; = p.L11V on NM_020631.6) | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV61702193; called by muse, mutect2, varscan2
- PRPF40B | c.1000G>C p.E334Q (on ENST00000380281; = p.E328Q on NM_012272.3) | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV56059479; called by muse, mutect2, varscan2
- PTPRH | c.1967C>T p.T656M | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as rs767010813, COSV54745669; called by muse, mutect2, varscan2
- RANBP10 | c.946C>G p.R316G | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs774958045, COSV58157824; called by muse, mutect2, varscan2
- RYR2 | c.8759G>A p.R2920Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs756302327, COSV63686833; called by muse, varscan2
- SERPINA10 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as rs533103231, COSV56228331; called by muse, mutect2
- SNTG2 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1444627239, COSV57975870; called by muse, mutect2, varscan2
- STAG1 | c.3002del p.L1001Rfs*7 | Frame Shift Del (DEL) | VAF 58/102 reads (57%) | catalogued as COSV52611724, COSV52625643; called by mutect2, pindel, varscan2
- STX7 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 83/137 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773741919, COSV63398748; called by muse, mutect2, varscan2
- TLL1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as rs746817970, COSV50281680; called by muse, mutect2, varscan2
- TMPRSS6 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs771121196, COSV60978400; called by muse, mutect2, varscan2
- TPX2 | c.1405G>T p.D469Y | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55919766; called by muse, mutect2, varscan2
- TTN | c.80053C>T p.R26685W (on ENST00000591111; = p.R19261W on NM_003319.4) | Missense Mutation (SNP) | VAF 61/151 reads (40%) | PolyPhen probably damaging (0.96); catalogued as rs749633038, COSV60075667, COSV60324430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFRD1 | c.370del p.M124* | Frame Shift Del (DEL) | VAF 35/153 reads (23%) | called by mutect2, pindel, varscan2
- ZNF507 | c.2193_2215del p.N732Yfs*3 | Frame Shift Del (DEL) | VAF 24/174 reads (14%) | called by mutect2, pindel
- ATP6V0A4 | c.243C>T p.L81= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as rs137955459, COSV59474290; called by muse, mutect2, varscan2
- BMP3 | c.18G>A p.R6= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs368705872; called by muse, mutect2, varscan2
- CILP | c.3279C>A p.G1093= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV56024432; called by muse, mutect2, varscan2
- CLIC5 | c.960C>T p.D320= (on ENST00000185206 / NM_001370649.1; = p.D161= on NM_016929.5) | Silent (SNP) | VAF 61/170 reads (36%) | catalogued as rs146052023; called by muse, mutect2, varscan2
- DDX25 | c.948C>T p.Y316= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1224280416, COSV54990513; called by muse, mutect2, varscan2
- FLNC | c.6450C>T p.I2150= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs776206819, COSV57956186; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHG3 | c.144C>T p.S48= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs372541996; called by muse, mutect2
- MSLNL | c.1353C>T p.I451= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV53502336; called by mutect2, varscan2
- NLRP7 | c.1371C>T p.D457= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs1482841415, COSV60175037; called by muse, mutect2, varscan2
- OPA3 | c.528G>A p.A176= | Silent (SNP) | VAF 72/176 reads (41%) | catalogued as rs752240099, COSV54399142; called by muse, mutect2, varscan2
- RASA1 | c.1509A>G p.Q503= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV57195605; called by muse, mutect2, varscan2
- STEAP2 | c.1002C>T p.L334= | Silent (SNP) | VAF 13/173 reads (8%) | catalogued as COSV55291232; called by muse, mutect2
- SV2B | c.1911C>T p.G637= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as rs769375334, COSV57699865; called by muse, mutect2, varscan2
- TMEM132D | c.987C>T p.G329= | Silent (SNP) | VAF 66/99 reads (67%) | catalogued as rs147002439, COSV70619681; called by muse, mutect2, varscan2
- TRPC7 | c.1653C>T p.S551= | Silent (SNP) | VAF 68/152 reads (45%) | catalogued as rs575768183, COSV61458041; called by muse, mutect2, varscan2
- ZAN | c.6711C>T p.G2237= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs377384170, COSV100769240; called by muse, mutect2, varscan2
